Somatic mutation profile of tumor specimen MMRF_2079_1_BM_CD138pos (aliquot MMRF_2079_1_BM_CD138pos_T1_KHS5U_L08645) from MMRF case MMRF_2079, project MMRF-COMMPASS (Multiple Myeloma CoMMpass Study). Sex at birth: male; Vital status: Alive; Primary diagnosis: Multiple myeloma; Tissue or organ of origin: Bone marrow; Age at diagnosis: 62.8 years (22,942 days).
Specimen MMRF_2079_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 018c0ed5-d4af-4785-aa1a-30da846c9711.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MMRF_2079_1_PB_Whole (Blood Derived Normal), aliquot MMRF_2079_1_PB_Whole_C2_KHS5U_L08644; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/ff22655f-1093-44f4-8d00-73df983ab13c

The open-access MAF lists 62 somatic variants for this specimen: 25 protein-altering or splice-affecting, 9 silent, 28 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 23, 3'UTR 14, Silent 9, Intron 7, 5'Flank 4, Nonsense Mutation 1, 5'UTR 1, Frame Shift Del 1, RNA 1, 3'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- EVC | c.364C>T p.P122S | Missense Mutation (SNP) | VAF 16/226 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1407007311, CM131158; ClinVar: uncertain significance / likely pathogenic; called by muse, mutect2
- ART3 | c.264G>A p.M88I | Missense Mutation (SNP) | VAF 143/314 reads (46%) | SIFT tolerated (0.19); PolyPhen benign (0.007); catalogued as COSV61915112, COSV61916203; called by muse, mutect2, varscan2
- GAREM1 | c.1145C>T p.S382F | Missense Mutation (SNP) | VAF 140/265 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV52512471; called by muse, mutect2, varscan2
- GPR158 | c.1555C>A p.P519T | Missense Mutation (SNP) | VAF 88/212 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as COSV100892633; called by muse, mutect2, varscan2
- IGKV3-20 | c.330G>C p.Q110H | Missense Mutation (SNP) | VAF 25/110 reads (23%) | SIFT tolerated (0.08); PolyPhen benign (0.145); catalogued as rs543059789; called by muse, mutect2, varscan2
- IGKV3-20 | c.211G>A p.G71S | Missense Mutation (SNP) | VAF 26/66 reads (39%) | SIFT tolerated (0.54); PolyPhen benign (0.027); catalogued as rs11546045; called by muse, varscan2
- IL13RA2 | c.1028G>T p.R343L | Missense Mutation (SNP) | VAF 68/68 reads (100%) | SIFT tolerated (0.75); PolyPhen benign (0); catalogued as COSV54567739; called by muse, mutect2, varscan2
- MYOM3 | c.1726C>T p.R576* | Nonsense Mutation (SNP) | VAF 139/328 reads (42%) | catalogued as rs754607808, COSV100292365; called by muse, mutect2, varscan2
- SGCG | c.143T>C p.V48A | Missense Mutation (SNP) | VAF 58/133 reads (44%) | SIFT deleterious (0); PolyPhen benign (0.133); catalogued as rs754949325; called by muse, mutect2, varscan2
- SIPA1L3 | c.146C>T p.P49L | Missense Mutation (SNP) | VAF 56/212 reads (26%) | SIFT deleterious (0.04); PolyPhen benign (0.006); catalogued as rs760130502; called by muse, mutect2, varscan2
- BCAN | c.1344G>T p.E448D | Missense Mutation (SNP) | VAF 65/137 reads (47%) | SIFT tolerated (0.18); PolyPhen benign (0.011); called by muse, mutect2, varscan2
- CACNA1A | c.2105A>G p.N702S | Missense Mutation (SNP) | VAF 69/306 reads (23%) | SIFT tolerated (0.16); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- CACTIN | c.705G>C p.R235S | Missense Mutation (SNP) | VAF 84/284 reads (30%) | SIFT tolerated (0.06); PolyPhen benign (0.029); called by muse, mutect2, varscan2
- CNDP2 | c.26A>C p.K9T | Missense Mutation (SNP) | VAF 211/474 reads (45%) | SIFT tolerated (0.11); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- DNAH5 | c.545G>A p.G182D | Missense Mutation (SNP) | VAF 93/372 reads (25%) | SIFT tolerated (0.38); PolyPhen benign (0.012); called by muse, mutect2, varscan2
- GART | c.1156G>C p.V386L | Missense Mutation (SNP) | VAF 120/412 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.951); called by muse, mutect2, varscan2
- GLYAT | c.345A>G p.I115M | Missense Mutation (SNP) | VAF 86/299 reads (29%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.544); called by muse, mutect2, varscan2
- HNRNPD | c.854G>A p.G285D (on ENST00000313899 / NM_031370.3; = p.G266D on NM_031369.2) | Missense Mutation (SNP) | VAF 18/37 reads (49%) | SIFT deleterious (0.01); PolyPhen benign (0.084); called by muse, mutect2, varscan2
- HPX | c.735del p.N246Tfs*16 | Frame Shift Del (DEL) | VAF 50/176 reads (28%) | called by mutect2, pindel, varscan2
- IGHV2-70D | c.215T>C p.I72T | Missense Mutation (SNP) | VAF 82/154 reads (53%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.703); called by mutect2, varscan2
- IGHV2-70D | c.76T>G p.S26A | Missense Mutation (SNP) | VAF 70/151 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); called by muse, varscan2
- IGKV3-20 | c.19C>A p.L7I | Missense Mutation (SNP) | VAF 20/39 reads (51%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.516); called by muse, varscan2
- NCKIPSD | c.1102A>G p.M368V | Missense Mutation (SNP) | VAF 33/95 reads (35%) | SIFT tolerated (0.52); PolyPhen benign (0); called by muse, mutect2, varscan2
- SSTR5 | c.191T>G p.V64G | Missense Mutation (SNP) | VAF 62/140 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- TRAM1L1 | c.910A>T p.S304C | Missense Mutation (SNP) | VAF 274/547 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.926); called by muse, mutect2, varscan2
- AAR2 | c.1170C>A p.V390= | Silent (SNP) | VAF 60/115 reads (52%) | called by muse, mutect2, varscan2
- ADCY1 | c.3048C>T p.G1016= | Silent (SNP) | VAF 213/366 reads (58%) | catalogued as rs1401322034, COSV99811440; called by muse, mutect2, varscan2
- AP5Z1 | c.498C>A p.G166= | Silent (SNP) | VAF 40/101 reads (40%) | called by muse, mutect2, varscan2
- IGHV5-51 | c.231C>T p.T77= | Silent (SNP) | VAF 110/279 reads (39%) | catalogued as rs782596821; called by muse, varscan2
- KCNT1 | c.1596C>T p.R532= (on ENST00000488444; = p.R551= on NM_020822.3) | Silent (SNP) | VAF 273/546 reads (50%) | catalogued as COSV53704705; called by muse, mutect2, varscan2
- KRT1 | c.1740C>T p.S580= | Silent (SNP) | VAF 17/39 reads (44%) | catalogued as rs771998586; called by muse, mutect2, varscan2
- TEX13A | c.744C>T p.L248= | Silent (SNP) | VAF 81/84 reads (96%) | called by muse, mutect2, varscan2
- THSD1 | c.1389G>T p.S463= | Silent (SNP) | VAF 116/265 reads (44%) | catalogued as COSV51627864; called by muse, mutect2, varscan2
- TRIO | c.2118G>C p.V706= | Silent (SNP) | VAF 77/316 reads (24%) | called by muse, mutect2, varscan2
- AC093334.1 | n.67T>C | RNA (SNP) | VAF 164/719 reads (23%) | called by muse, mutect2, varscan2
- AKR1C4 | chr10:5196667 del T | 5'Flank (DEL) | VAF 34/74 reads (46%) | called by mutect2, pindel
- ANTXR2 | chr4:80073127 C>T | 5'Flank (SNP) | VAF 89/166 reads (54%) | called by muse, mutect2, varscan2
- ARMH4 | c.*273G>A | 3'UTR (SNP) | VAF 55/149 reads (37%) | called by muse, mutect2, varscan2
- BCL9L | c.*1824C>A | 3'UTR (SNP) | VAF 61/263 reads (23%) | called by muse, mutect2, varscan2
- BRSK2 | c.*1576G>C | 3'UTR (SNP) | VAF 157/429 reads (37%) | called by muse, mutect2, varscan2
- CACTIN | chr19:3610649 T>C | 3'Flank (SNP) | VAF 144/219 reads (66%) | called by muse, mutect2, varscan2
- CBX5 | c.*334G>A | 3'UTR (SNP) | VAF 37/115 reads (32%) | called by muse, mutect2, varscan2
- COX7C | c.*72A>G | 3'UTR (SNP) | VAF 47/144 reads (33%) | called by muse, mutect2, varscan2
- CWC27 | c.938+3683C>G | Intron (SNP) | VAF 56/98 reads (57%) | called by muse, mutect2, varscan2
- FNDC3B | c.*2686T>C | 3'UTR (SNP) | VAF 54/169 reads (32%) | called by muse, mutect2, varscan2
- GEMIN5 | c.*594T>C | 3'UTR (SNP) | VAF 64/198 reads (32%) | called by muse, mutect2, varscan2
- GOPC | c.*904G>C | 3'UTR (SNP) | VAF 8/121 reads (7%) | called by muse, mutect2
- GRAMD2B | c.84-90A>G | Intron (SNP) | VAF 198/297 reads (67%) | called by muse, mutect2, varscan2
- IGHJ6 | chr14:105863447 T>A | 5'Flank (SNP) | VAF 9/16 reads (56%) | catalogued as rs909501817; called by muse, varscan2
- IKZF1 | c.161-8280T>C | Intron (SNP) | VAF 105/364 reads (29%) | catalogued as COSV58783327; called by muse, mutect2, varscan2
- INMT | c.*190C>T | 3'UTR (SNP) | VAF 23/81 reads (28%) | called by muse, mutect2, varscan2
- IRF8 | c.554-140A>T | Intron (SNP) | VAF 46/103 reads (45%) | called by muse, mutect2, varscan2
- KIAA1958 | c.*7624A>C | 3'UTR (SNP) | VAF 83/408 reads (20%) | called by muse, mutect2, varscan2
- LAMC1 | c.*2134C>T | 3'UTR (SNP) | VAF 77/168 reads (46%) | called by muse, mutect2, varscan2
- MYL10 | c.-27A>T | 5'UTR (SNP) | VAF 161/268 reads (60%) | catalogued as rs554110292, COSV56207366; called by muse, mutect2, varscan2
- PRKACB | c.765+2510C>T | Intron (SNP) | VAF 7/57 reads (12%) | called by muse, mutect2, varscan2
- PTGIS | c.*326C>A | 3'UTR (SNP) | VAF 77/164 reads (47%) | called by muse, mutect2, varscan2
- RNA5-8SP2 | chr16:34159906 C>A | 5'Flank (SNP) | VAF 7/15 reads (47%) | catalogued as rs8048216; called by muse, varscan2
- SLC36A4 | c.*51C>T | 3'UTR (SNP) | VAF 14/46 reads (30%) | called by muse, mutect2, varscan2
- SLC5A1 | c.584-11T>C | Intron (SNP) | VAF 122/290 reads (42%) | called by muse, mutect2, varscan2
- UBE2V2 | c.*3125T>A | 3'UTR (SNP) | VAF 13/28 reads (46%) | called by muse, mutect2, varscan2
- UHRF1BP1L | c.44+13940C>G | Intron (SNP) | VAF 81/160 reads (51%) | called by muse, mutect2, varscan2
